Surgical pathology report (de-identified scan), TCGA case TCGA-85-8481, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Asterand, specimen TCGA-85-8481-01A (Primary Tumor).

[page 1 of 3]
TCGA Pathology

Case ID	Gross Description	Microscopic Description	Diagnosis Details
	Lobe with free bronchus; on section, in the posterior segment, there is a parahilar tumoral structure of approximately 5.5/4.5/4.5 cm in diameter, which also invades a parietal fragment with 2 rib fragments; the tumor is relatively well-limited, white-grey colored, with hotbeds of necrosis.	TUMOR FRAGMENT (with parietal invasion): Bronchopulmonary neoplasm of the spinocellular epidermoid carcinoma type without keratinization, G2, formed of solid beaches of relatively monomorphous cells, with relatively frequent atypias, with hotbeds of necrosis; abundant fibrous-inflammatory stroma; the tumoral infiltrates penetrate the fibro-muscular parietal layer; osseous tissue without tumoral infiltration. INTERLOBAR LYMPH NODE: Without tumoral aspect. PHRENIC CHAIN LYMPH NODE: No metastases. LYMPH NODE STATION VI: No metastases. LOWER LOBAR BRONCHUS LYMPH NODE: No metastases.	

[page 2 of 3]
Comments	Formatted Path Report
	LUNG TISSUE CHECKLIST Specimen type: Lobectomy Tumor site: Lung Tumor size: 5.5 x 4.5 x 4.5 cm Histologic type: Squamous cell carcinoma Histologic grade: Moderately differentiated Tumor extent: Parietal pericardium Other tumor nodules: Not specified Lymph nodes: 0/4 positive for metastasis (St.11,4,6 0/4) Lymphatic invasion: Present Venous invasion: Not specified Margins: Not specified Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None

OpenClinica ID

[page 3 of 3]
Excision date

Laterality

Left- upper

Source: NCI Genomic Data Commons file d10ebf86-2f2c-4331-8357-a0da67be9ba7 (TCGA-85-8481.92102BFF-29A9-4D0E-9C97-73883E8E4199.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).